Somatic mutation profile of tumor specimen TCGA-98-A53J-01A (aliquot TCGA-98-A53J-01A-11D-A26M-08) from TCGA case TCGA-98-A53J, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 78.0 years (28,485 days).
Specimen TCGA-98-A53J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5e540f5-0a7b-4b54-af45-fe3eb9f4dd85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-98-A53J-10A (Blood Derived Normal), aliquot TCGA-98-A53J-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29a57fce-f3c1-44f5-8852-99f87f2f784b

The open-access MAF lists 121 somatic variants for this specimen: 90 protein-altering or splice-affecting, 29 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 29, Nonsense Mutation 4, Splice Site 2, Frame Shift Del 2, Nonstop Mutation 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLF5 | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66613960, COSV66613967; called by muse, mutect2, varscan2
- ABCA10 | c.4168G>T p.E1390* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV99289062; called by muse, mutect2, varscan2
- ABCA3 | c.4984-1G>A p.X1662_splice | Splice Site (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100068240, COSV100068908; called by muse, mutect2, varscan2
- ABCC12 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV100253001, COSV60913594; called by muse, mutect2, varscan2
- ACKR1 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.174); catalogued as COSV100929619; called by muse, mutect2, varscan2
- ADCY8 | c.3176A>G p.H1059R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99653413; called by muse, mutect2, varscan2
- ADGRG6 | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.787); catalogued as COSV99748089; called by muse, mutect2, varscan2
- ALKBH5 | c.243G>C p.E81D | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99233769; called by muse, mutect2, varscan2
- ANGPTL1 | c.302T>C p.V101A | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99328298; called by muse, mutect2, varscan2
- ANKRD17 | c.5870C>T p.S1957F | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.367); catalogued as COSV100429682; called by muse, mutect2, varscan2
- C1QTNF2 | c.206G>A p.R69H (on ENST00000393975; = p.R24H on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs369887111, COSV101220882; called by muse, varscan2
- CBLB | c.1727A>G p.H576R | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.046); catalogued as COSV99913948; called by muse, mutect2, varscan2
- CLN8 | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58670884; called by muse, mutect2, varscan2
- CMYA5 | c.1354G>T p.D452Y | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV101484229; called by muse, mutect2, varscan2
- CNTRL | c.4432G>A p.E1478K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.081); catalogued as COSV53045336; called by muse, mutect2, varscan2
- COLGALT1 | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as COSV53108853, COSV99395048; called by muse, mutect2
- DCAF12L2 | c.145C>G p.R49G | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV100758738, COSV63583066; called by muse, mutect2, varscan2
- DDA1 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100724880; called by muse, mutect2, varscan2
- DPP10 | c.1345G>C p.G449R | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100069616; called by muse, mutect2, varscan2
- EPB41L2 | c.2144C>T p.S715L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV61359573; called by muse, mutect2, varscan2
- FAM210A | c.655C>A p.H219N | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100452457; called by muse, mutect2
- FAM78A | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1466507860, COSV100953432, COSV64844980; called by muse, mutect2, varscan2
- FBLL1 | c.1005G>C p.*335Yext*26 | Nonstop Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100606186; called by muse, mutect2
- FILIP1 | c.3475C>T p.R1159C | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766720526, COSV99385613; called by muse, mutect2, varscan2
- GPR139 | c.812A>T p.N271I | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100429964; called by muse, mutect2, varscan2
- HAPLN1 | c.345G>T p.K115N | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99165099; called by muse, mutect2, varscan2
- HERC1 | c.10735T>C p.Y3579H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.259); catalogued as COSV101496754; called by muse, varscan2
- HFE | c.643C>T p.H215Y | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs778399184, COSV58512414; called by muse, mutect2, varscan2
- HHATL | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.912); catalogued as rs568465929, COSV100124551; called by muse, mutect2, varscan2
- IL16 | c.622G>C p.G208R | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV100267888; called by muse, mutect2, varscan2
- IL1RAP | c.842G>T p.W281L | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99300024; called by muse, mutect2, varscan2
- IQGAP3 | c.1290+1G>T p.X430_splice | Splice Site (SNP) | VAF 18/70 reads (26%) | catalogued as COSV100752243; called by muse, mutect2, varscan2
- ITIH5 | c.613C>G p.L205V | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV99905317; called by muse, mutect2, varscan2
- KALRN | c.8371C>A p.L2791M (on ENST00000360013 / NM_001024660.4; = p.L1094M on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99362562; called by muse, mutect2, varscan2
- LAMA5 | c.7615G>A p.A2539T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99441302; called by muse, mutect2, varscan2
- LIG4 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.092); catalogued as COSV100799998; called by muse, mutect2, varscan2
- MARK2 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100158934; called by muse, mutect2, varscan2
- MCAM | c.394G>T p.V132F | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99877876; called by muse, mutect2, varscan2
- MYBPC3 | c.2128G>T p.E710* | Nonsense Mutation (SNP) | VAF 35/117 reads (30%) | catalogued as CM118275, COSV99920753; called by muse, mutect2, varscan2
- MYOT | c.1133C>A p.P378Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99296532; called by muse, mutect2
- MYOT | c.1135A>G p.K379E | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs746057064, COSV99296533; called by muse, mutect2
- NAGS | c.719C>A p.S240* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as rs781031762, COSV99517935; called by muse, mutect2
- NF1 | c.2425C>A p.H809N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.065); catalogued as COSV100647809, COSV62199998; called by muse, mutect2, varscan2
- NKX2-1 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.273); catalogued as CM146079, COSV100701734, COSV61390068; called by muse, mutect2, varscan2
- NTRK2 | c.983A>G p.K328R | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.506); catalogued as rs200961252, COSV99457424; called by muse, mutect2, varscan2
- OR2G2 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1011627557, COSV60741672, COSV60742813; called by muse, mutect2, varscan2
- OR4C16 | c.290T>A p.I97N | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV100114188; called by muse, mutect2, varscan2
- PARD3B | c.788T>C p.V263A | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100594542; called by muse, mutect2, varscan2
- PCDH9 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.981); catalogued as COSV100122373; called by muse, mutect2, varscan2
- PCDH9 | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.998); catalogued as COSV100122377; called by muse, mutect2, varscan2
- PCLO | c.8947G>A p.G2983S | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.337); catalogued as rs1312410868; called by muse, mutect2
- PELO | c.1127A>C p.Q376P | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99251831; called by muse, mutect2, varscan2
- PLXNB2 | c.5301C>A p.D1767E | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100834199; called by muse, mutect2
- PTER | c.595A>T p.I199F | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV100126765; called by muse, mutect2, varscan2
- RAB11FIP3 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99240663; called by muse, mutect2
- RABEP1 | c.329G>A p.W110* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99336867; called by muse, mutect2, varscan2
- RANBP2 | c.961C>A p.L321I | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV99312783; called by muse, mutect2, varscan2
- RANBP3 | c.1080G>C p.Q360H (on ENST00000340578 / NM_007322.3; = p.Q355H on NM_003624.3) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.838); catalogued as COSV99222415; called by muse, mutect2, varscan2
- RELT | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs377396969; called by mutect2, varscan2
- RNLS | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs773555002, COSV100076872; called by muse, mutect2, varscan2
- RPGRIP1L | c.1538G>T p.R513I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100046599; called by mutect2, varscan2
- SESN2 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV53427715; called by muse, mutect2, varscan2
- SETD1A | c.1744G>A p.D582N | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.189); catalogued as rs1235564272, COSV99353456; called by muse, mutect2, varscan2
- SLC9A5 | c.784G>T p.A262S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100237470; called by muse, mutect2
- SOX6 | c.2093G>T p.C698F (on ENST00000528429 / NM_001145819.2; = p.C671F on NM_017508.3) | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100322783; called by muse, mutect2, varscan2
- SOX6 | c.2092T>A p.C698S (on ENST00000528429 / NM_001145819.2; = p.C671S on NM_017508.3) | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100322784; called by muse, mutect2, varscan2
- SUGP1 | c.1174G>T p.D392Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs1289822512, COSV99895349; called by muse, mutect2, varscan2
- TASP1 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV100534736; called by muse, mutect2, varscan2
- TICRR | c.4339A>C p.S1447R | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99177584; called by muse, mutect2, varscan2
- TMEM242 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.293); catalogued as rs868955517, COSV65653985; called by muse, mutect2, varscan2
- TNR | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs765830482, COSV54907165; called by muse, mutect2, varscan2
- TRA2A | c.692G>A p.G231D | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV99767467; called by muse, mutect2, varscan2
- TRPV5 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs771239971, COSV54682696; called by muse, mutect2, varscan2
- TTN | c.87056G>A p.R29019Q (on ENST00000591111; = p.R21595Q on NM_003319.4) | Missense Mutation (SNP) | VAF 18/65 reads (28%) | PolyPhen probably damaging (0.996); catalogued as rs765986284, COSV100622729; called by muse, mutect2, varscan2
- USP3 | c.253T>C p.C85R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99165765; called by muse, mutect2
- WDR83 | c.698A>C p.K233T | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.516); catalogued as COSV99269719; called by muse, mutect2, varscan2
- WFDC2 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs202089413, COSV54151049; called by muse, mutect2, varscan2
- ZNF273 | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100139448; called by muse, mutect2, varscan2
- ZNF516 | c.1629G>C p.E543D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV101487333; called by muse, mutect2, varscan2
- ZNF680 | c.1429C>A p.L477I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV100549269, COSV59014326; called by muse, mutect2, varscan2
- ZNF700 | c.1628A>C p.K543T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs764934081, COSV99583697; called by muse, mutect2, varscan2
- ZNF800 | c.1634C>T p.S545L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV99758080; called by muse, mutect2, varscan2
- ZNF804A | c.2872G>A p.E958K | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.683); catalogued as COSV56477091; called by muse, varscan2
- ZNF804A | c.2920G>A p.E974K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56449383; called by muse, varscan2
- ZNF836 | c.2798C>T p.S933F | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.068); catalogued as COSV100441119, COSV59087257; called by muse, mutect2, varscan2
- DENND1B | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- GAREM1 | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2
- NEB | c.3701C>A p.T1234N | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- PTEN | c.728del p.F243Sfs*13 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- USH2A | c.1523del p.A508Efs*83 | Frame Shift Del (DEL) | VAF 13/87 reads (15%) | called by mutect2, pindel, varscan2
- ANGEL1 | c.1857C>T p.H619= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as COSV99200450; called by muse, mutect2, varscan2
- ASCL4 | c.327C>T p.L109= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV100661201; called by muse, mutect2, varscan2
- ATP11C | c.2625C>T p.H875= | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as COSV100558346; called by muse, mutect2, varscan2
- CNOT8 | c.345C>T p.L115= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV99597239; called by muse, mutect2, varscan2
- CSF2RB | c.1509C>T p.F503= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV99454217, COSV99454284; called by muse, mutect2, varscan2
- CSMD1 | c.4206C>A p.T1402= (on ENST00000520002; = p.T1401= on NM_033225.6) | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV100153861; called by muse, mutect2
- CUX2 | c.4369C>A p.R1457= | Silent (SNP) | VAF 55/142 reads (39%) | catalogued as COSV99920286; called by muse, mutect2, varscan2
- DGCR8 | c.316C>A p.R106= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as rs768183516, COSV100708091; called by muse, mutect2, varscan2
- DLL3 | c.1719G>T p.G573= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV99219322; called by muse, mutect2, varscan2
- EHMT1 | c.3138G>T p.V1046= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV101509718, COSV71777481; called by muse, mutect2, varscan2
- FUT5 | c.303G>T p.A101= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV53138045, COSV99398889; called by muse, mutect2, varscan2
- HERC1 | c.10734C>T p.C3578= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV101496755; called by muse, mutect2, varscan2
- IGKV1D-16 | c.27C>T p.L9= | Silent (SNP) | VAF 41/82 reads (50%) | catalogued as rs770188120; called by muse, mutect2, varscan2
- INVS | c.2658G>A p.G886= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV99317952; called by muse, mutect2, varscan2
- LDB2 | c.921G>A p.L307= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as COSV100454326; called by muse, mutect2, varscan2
- MATN1 | c.1242C>T p.A414= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as rs763489844, COSV101056390; called by muse, mutect2, varscan2
- NEB | c.19179C>T p.N6393= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as rs906146368, COSV99425851; called by muse, mutect2
- OR2T34 | c.489G>A p.L163= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as COSV100170457; called by muse, mutect2
- OR4C16 | c.291C>A p.I97= | Silent (SNP) | VAF 19/154 reads (12%) | catalogued as COSV58941944, COSV58943228; called by muse, mutect2, varscan2
- PCDHGA12 | c.1263A>T p.T421= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV99341424; called by muse, mutect2, varscan2
- SMG7 | c.612C>T p.T204= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs201231881; called by muse, mutect2, varscan2
- TINAG | c.777G>A p.Q259= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV52505238, COSV99450364; called by muse, mutect2, varscan2
- TNRC18 | c.1911C>T p.L637= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1335912922, COSV101259497; called by muse, mutect2, varscan2
- TRHR | c.1071C>T p.I357= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as COSV100304974; called by muse, mutect2, varscan2
- UCP1 | c.744C>T p.Y248= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as rs372823869; called by muse, mutect2, varscan2
- WDPCP | c.1734C>T p.F578= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs1195101119, COSV55432536; called by muse, mutect2, varscan2
- XIRP2 | c.141G>A p.R47= (on ENST00000628543; = p.R222= on NM_152381.6) | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as COSV99745582; called by muse, mutect2, varscan2
- ZIC3 | c.1314T>C p.S438= | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as COSV99799265; called by muse, mutect2, varscan2
- ZNF223 | c.30C>T p.F10= | Silent (SNP) | VAF 25/192 reads (13%) | catalogued as COSV101462646; called by muse, mutect2, varscan2
- ADGRG6 | c.*74G>A | 3'UTR (SNP) | VAF 26/91 reads (29%) | catalogued as COSV99748093; called by muse, mutect2, varscan2
- MIR524 | n.59G>T | RNA (SNP) | VAF 36/66 reads (55%) | called by muse, mutect2, varscan2
